Somatic mutation profile of tumor specimen TCGA-HU-A4H6-01A (aliquot TCGA-HU-A4H6-01A-11D-A25D-08) from TCGA case TCGA-HU-A4H6, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 72.4 years (26,445 days).
Specimen TCGA-HU-A4H6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17b76fcd-ef42-4d62-8d32-83e965995231.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4H6-10A (Blood Derived Normal), aliquot TCGA-HU-A4H6-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bba8cf65-e827-4a8a-bb18-b299fd85e397

The open-access MAF lists 104 somatic variants for this specimen: 77 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 73, Silent 27, Nonsense Mutation 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.1970T>G p.V657G | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV100741659; called by muse, mutect2
- ABHD8 | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99917111; called by muse, mutect2
- ADIPOR2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs1471945661, COSV63947120; called by muse, mutect2, varscan2
- AHNAK | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99945518, COSV99950251; called by muse, mutect2, varscan2
- ANGPTL5 | c.931C>G p.R311G | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.185); catalogued as COSV57531925, COSV57533782; called by muse, mutect2, varscan2
- APOA1 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.084); catalogued as COSV52636149; called by muse, mutect2, varscan2
- ASB17 | c.77T>A p.I26N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as COSV52411176; called by muse, mutect2, varscan2
- ATP8B2 | c.1208C>T p.T403M (on ENST00000672630; = p.T370M on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.394); catalogued as rs1050193940, COSV59247342; called by muse, mutect2, varscan2
- BCL11A | c.2023G>A p.G675R (on ENST00000335712 / NM_001365609.1; = p.G709R on NM_018014.4) | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59633727; called by muse, mutect2, varscan2
- CCT8L2 | c.1459A>C p.N487H | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63463151; called by muse, mutect2
- CDHR4 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs372659412; called by muse, mutect2, varscan2
- CLCN1 | c.32G>T p.G11V | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.051); catalogued as CD1313408, COSV58372115; called by muse, mutect2, varscan2
- CLCNKB | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 23/207 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.597); catalogued as COSV65161203; called by muse, mutect2, varscan2
- CPNE5 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs992993546, COSV55198812; called by muse, mutect2
- CRYGN | c.273C>T p.H91= | Splice Region (SNP) | VAF 8/55 reads (15%) | catalogued as rs146240466; called by muse, mutect2, varscan2
- CTSH | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1293224316, COSV99585346; called by muse, mutect2, varscan2
- CYFIP2 | c.2530A>G p.S844G (on ENST00000616178 / NM_001291722.2; = p.S819G on NM_014376.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56637299; called by muse, mutect2, varscan2
- DMXL1 | c.4767G>A p.M1589I | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV60716648; called by muse, mutect2, varscan2
- EBF1 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs768597902, COSV100565638, COSV58180298; called by muse, mutect2, varscan2
- F13A1 | c.1871A>C p.K624T | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.378); catalogued as COSV53554800; called by muse, mutect2
- FMO3 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.363); catalogued as COSV63007917; called by muse, mutect2
- FRMD6 | c.673C>T p.R225* (on ENST00000344768 / NM_001267046.2; = p.R217* on NM_152330.4) | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100655564, COSV61089604; called by muse, mutect2
- GALNT17 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61174372; called by muse, mutect2, varscan2
- GALNT3 | c.813A>T p.E271D | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as COSV67062063; called by muse, mutect2
- GCNA | c.543C>A p.D181E | Missense Mutation (SNP) | VAF 36/407 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV65467574; called by muse, mutect2
- GORAB | c.314G>A p.S105N | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV63026463; called by muse, mutect2, varscan2
- HRC | c.1984T>C p.C662R | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53257554; called by muse, mutect2, varscan2
- HTT | c.6775G>T p.A2259S | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as COSV61865498; called by muse, mutect2, varscan2
- IFIT1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs924548286, COSV100878663; called by muse, mutect2, varscan2
- ITGA9 | c.286A>G p.R96G | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV99291588; called by muse, mutect2
- LAIR1 | c.591dup p.R198Qfs*14 | Frame Shift Ins (INS) | VAF 17/158 reads (11%) | catalogued as rs760699396; called by mutect2, pindel, varscan2
- LIPN | c.491A>C p.Q164P | Missense Mutation (SNP) | VAF 8/197 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101356252; called by muse, mutect2
- MTNR1B | c.545A>C p.E182A | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as COSV57067514; called by muse, mutect2, varscan2
- MYH11 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773587055, COSV55558968; called by muse, mutect2, varscan2
- MYH2 | c.5707C>T p.R1903C | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777766586, COSV55437322; called by muse, mutect2, varscan2
- NAV3 | c.1330C>T p.P444S | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0.015); catalogued as COSV57088012; called by muse, mutect2, varscan2
- NDST1 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.242); catalogued as COSV55788879; called by muse, mutect2
- NOB1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as rs746189885, COSV52061373; called by muse, mutect2, varscan2
- OR2T3 | c.900A>C p.K300N | Missense Mutation (SNP) | VAF 34/338 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100613062; called by muse, mutect2
- OR52H1 | c.644T>C p.L215P (on ENST00000322653; = p.L221P on NM_001005289.1) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59505862; called by muse, mutect2, varscan2
- PCDH18 | c.2542A>G p.S848G | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.423); catalogued as COSV100787028, COSV61271459; called by muse, mutect2
- PCDHA2 | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 38/219 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV65369028; called by muse, mutect2, varscan2
- PDS5B | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 22/239 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1224573363, COSV59730478; called by muse, mutect2
- PEAK3 | c.68C>T p.T23M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs141253643; called by muse, mutect2, varscan2
- PKDCC | c.1094A>G p.D365G | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV99684657; called by muse, mutect2
- POGK | c.1798T>A p.C600S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV63311972; called by muse, mutect2
- PPFIBP2 | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 22/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100207132, COSV55079802; called by muse, varscan2
- PPP4C | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as rs1388779212, COSV54222589; called by muse, mutect2
- RNF25 | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV55308523; called by muse, mutect2, varscan2
- RPAP1 | c.3295A>T p.T1099S | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58540887; called by muse, mutect2
- RSAD1 | c.731C>G p.A244G | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV51956359, COSV99364448; called by muse, mutect2, varscan2
- RTL5 | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.02); catalogued as rs1438886636, COSV65454154; called by muse, mutect2, varscan2
- RXFP2 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1043084858, COSV53634652; called by muse, mutect2
- RYR1 | c.3071G>A p.R1024H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs148146893; called by muse, mutect2, varscan2
- SEMA3C | c.2087C>A p.A696E | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV54851225; called by muse, mutect2, varscan2
- SEMA4D | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs542114524, COSV59397611; called by muse, mutect2, varscan2
- SH3RF2 | c.1798C>T p.L600F | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV63040214; called by muse, mutect2, varscan2
- SLC39A10 | c.1496T>G p.L499R | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62768316; called by muse, mutect2, varscan2
- SPATA7 | c.1538C>T p.T513I | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV99247723; called by muse, mutect2
- SPRTN | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV50478768; called by muse, mutect2
- STK32B | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371890370; called by muse, mutect2
- SYNE1 | c.14869G>A p.E4957K (on ENST00000367255 / NM_182961.4; = p.E4886K on NM_033071.3) | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.094); catalogued as COSV55036050; called by muse, mutect2
- TCF12 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99976209; called by muse, varscan2
- THOC5 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758325423, COSV63799721; called by muse, mutect2
- TNKS1BP1 | c.3533C>G p.S1178C | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100835797, COSV100835878; called by muse, mutect2
- TNRC6B | c.1516G>A p.V506I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.891); catalogued as rs1412700883, COSV57309595; called by muse, mutect2
- TREML4 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV58385635; called by muse, mutect2, varscan2
- URI1 | c.1576T>C p.F526L | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56351523; called by muse, mutect2, varscan2
- VSIG2 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.012); catalogued as COSV99423038; called by muse, mutect2
- WDR11 | c.2555C>T p.S852F | Missense Mutation (SNP) | VAF 17/597 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV99676981; called by muse, mutect2
- XKR7 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.489); catalogued as rs147437006; called by muse, mutect2, varscan2
- ZAP70 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1266171275, COSV53852956; called by muse, mutect2, varscan2
- ZBTB21 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as rs374335079; called by muse, mutect2, varscan2
- ZNF385D | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as rs758875450, COSV55749750; called by muse, mutect2, varscan2
- ZNF506 | c.948G>T p.E316D | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as rs554073130, COSV71354351, COSV71354510; called by muse, mutect2, varscan2
- ZNF707 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV62311114; called by muse, mutect2, varscan2
- ZNF784 | c.774C>G p.D258E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV57596465; called by muse, mutect2
- ABCA3 | c.4170C>T p.Y1390= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as rs532847219, COSV57056569; called by muse, mutect2, varscan2
- ARCN1 | c.225C>T p.N75= | Silent (SNP) | VAF 30/131 reads (23%) | catalogued as rs1555074624, COSV50616218; called by muse, mutect2, varscan2
- C1QL1 | c.549C>T p.R183= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as COSV53647676; called by muse, varscan2
- CA5A | c.4T>C p.L2= | Silent (SNP) | VAF 6/127 reads (5%) | catalogued as COSV99990394; called by muse, mutect2
- CACNA1H | c.3630G>A p.P1210= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs764420422, COSV61997454; ClinVar: likely benign; called by muse, mutect2, varscan2
- CACNG2 | c.426C>T p.F142= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as rs750586750, COSV55632594, COSV55633797; called by muse, mutect2
- CTSC | c.1290C>T p.G430= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV57058970; called by muse, mutect2
- CYP4X1 | c.666C>T p.I222= | Silent (SNP) | VAF 15/186 reads (8%) | catalogued as rs1356232607, COSV64151250; called by muse, mutect2
- EDRF1 | c.2022A>C p.G674= (on ENST00000356792 / NM_001202438.2; = p.G640= on NM_015608.2) | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV61765102; called by muse, mutect2, varscan2
- FAM120A | c.840C>T p.D280= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs745807056, COSV52908964, COSV52909382; called by muse, mutect2, varscan2
- FZD2 | c.1332C>A p.I444= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100190215; called by muse, mutect2
- GPR153 | c.228C>T p.F76= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs772445791, COSV64938755; called by muse, mutect2, varscan2
- GPR179 | c.3096G>A p.R1032= (on ENST00000621958; = p.R1031= on NM_001004334.4) | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as rs752341496; called by muse, mutect2, varscan2
- MYD88 | c.510C>T p.S170= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs1415804686, COSV57177107; called by muse, mutect2
- NPR2 | c.880T>C p.L294= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as rs1303946040, COSV61312823; called by muse, mutect2
- NRP1 | c.1716C>A p.G572= | Silent (SNP) | VAF 21/198 reads (11%) | catalogued as COSV55171669, COSV99589814; called by muse, mutect2, varscan2
- PCDHA4 | c.2046G>A p.A682= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV63540205; called by muse, mutect2
- PCDHB8 | c.1386C>T p.R462= | Silent (SNP) | VAF 25/249 reads (10%) | catalogued as rs782363540, COSV99175595; called by muse, mutect2, varscan2
- PTPRF | c.3339C>T p.D1113= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs148630488; called by muse, mutect2, varscan2
- PTPRR | c.387C>T p.N129= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as rs1245791243, COSV51739033; called by muse, mutect2
- SCRT2 | c.504G>A p.S168= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs774898435, COSV55729302; called by muse, mutect2, varscan2
- SLC17A3 | c.978C>T p.C326= | Silent (SNP) | VAF 36/124 reads (29%) | catalogued as rs571118874, COSV57760828; called by muse, mutect2, varscan2
- SLC29A2 | c.831G>A p.K277= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV60803640; called by muse, mutect2, varscan2
- TMLHE | c.408C>T p.N136= | Silent (SNP) | VAF 9/171 reads (5%) | catalogued as COSV100544577; called by muse, mutect2
- TNR | c.1710C>T p.Y570= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as rs746969510, COSV54899996; called by muse, mutect2
- VCX | c.303C>T p.H101= | Silent (SNP) | VAF 24/254 reads (9%) | catalogued as rs151212725, COSV58232329; called by muse, varscan2
- ZNF43 | c.1314C>T p.P438= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100731966, COSV61684821; called by muse, mutect2, varscan2
